Gene-level copy-number profile of tumor specimen TCGA-ZM-AA06-01A from TCGA case TCGA-ZM-AA06, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 45.8 years (16,719 days).
Specimen TCGA-ZM-AA06-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.1f05bb38-aa99-4b6f-b761-2593c7c9fd2e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZM-AA06-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e0c205cb-e0f8-441a-82bb-bb32a1e33627

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 42; copy number 1: 31; copy number 2: 26,611; copy number 3: 26,580; copy number 4: 5,304; copy number 5: 607; copy number 6: 501; copy number 7: 74; copy number 32: 66.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZM-AA06-01A-12D-A434-01): tumor purity 0.58, ploidy 2.67, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:53,815,419–60,163,928, 42 genes (within-gene range 0–2): LINC00558, LINC00458, AL356052.1, MIR1297, RPL13AP25, AL442636.1, AL512655.1, AL390964.1, LINC02335, AL139038.1, MIR5007, AL354821.1, HNF4GP1, AL138997.1, SPATA2P1, RN7SKP6, PRR20A, PRR20C, PRR20B, PRR20D, PRR20E, PRR20FP, MTCO2P3, SLC25A5P4, RPL31P53, PCDH17, AL445288.1, RNA5SP30, LINC02338, LINC00374, AL161423.1, RNY4P29, CTAGE16P, DNAJA1P1, HMGN2P39, POLR3KP1, AL159156.1, RPP40P2, RNU7-88P, DIAPH3, DIAPH3-AS1, RN7SL375P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 140 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:54,381,698–55,773,407, 16 genes, copy number 7 (within-gene range 3–7): AC027250.2, RN7SL250P, SOX17, AC091076.1, TRMT112P7, RP1, SEC11B, AC090151.1, AC084834.1, XKR4, AC022679.2, AC022679.1, SBF1P1, AC090200.1, TMEM68, RNA5SP265.
- chr8:62,855,068–66,518,524, 58 genes, copy number 7: XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P, AC011124.1, IFITM8P, AC011124.2, AC018953.1, RN7SKP135, AC018953.2, LINC01414, AC069133.1, LINC01289, COX6CP8, MIR124-2HG, MIR124-2, AC012535.1, AC090136.1, AC090136.2, AC090136.3, BHLHE22, CYP7B1, AC104232.2, AC104232.3, AC104232.1, AC087808.1, RPL31P41, LINC00251, PPIAP86, LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P.
- chr12:68,805,011–72,186,618, 66 genes, copy number 32 (within-gene range 4–32) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 31. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
